Somatic mutation profile of tumor specimen ALCH-B3IK-TTP1-A (aliquot ALCH-B3IK-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.0 years (20,464 days).
Specimen ALCH-B3IK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cec4f0b-07a5-47df-a961-509227ed582a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IK-NB1-A (Blood Derived Normal), aliquot ALCH-B3IK-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d7b01d9-74af-42ac-b2b5-4dea6a0fcb46

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1732G>C p.V578L | Missense Mutation (SNP) | VAF 58/619 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs769859765; called by muse, mutect2
- MAX | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 47/559 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM122945; called by muse, mutect2
- ZSCAN23 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs549900637; called by muse, mutect2
- AKAP9 | c.5062G>A p.G1688R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.29); called by muse, varscan2
- AKR7L | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 31/397 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.419); called by muse, mutect2
- ALG6 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C11orf24 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.415); called by muse, mutect2
- DOCK2 | c.2448C>G p.S816R | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KDM5A | c.2062C>G p.L688V | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.272); called by muse, mutect2
- NYX | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PCDHA4 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 15/433 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.417); called by muse, mutect2
- TFR2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- BDNF | c.135C>T p.S45= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs747701929; called by muse, mutect2
- FGD5 | c.3300C>T p.S1100= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as rs768322407; called by muse, mutect2
- GLT6D1 | c.492C>T p.D164= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as rs370736696; called by muse, mutect2
- RHD | c.1041G>A p.L347= | Silent (SNP) | VAF 52/580 reads (9%) | catalogued as rs777114029; called by muse, mutect2
- TKTL1 | c.568C>A p.R190= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- WDR37 | c.924C>T p.Y308= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs747325196, COSV99579964; called by muse, mutect2
- FHL1 | c.*843C>T | 3'UTR (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
